Somatic mutation profile of tumor specimen 0DQC21 from CCDI case PBCELM, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Overlapping lesion of nasopharynx; Age at diagnosis: 6.0 years (2,205 days).
Specimen 0DQC21: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4b7f5703-72af-4d24-9281-a9cca88305e1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQC25 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9067d15b-fd7b-45fa-890e-2c09825cca37

The open-access MAF lists 37 somatic variants for this specimen: 24 protein-altering or splice-affecting, 10 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 10, Frame Shift Del 3, Intron 2, Splice Site 2, Nonsense Mutation 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTL9 | c.1210G>A p.E404K | Missense Mutation (SNP) | VAF 57/239 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.324); catalogued as rs782524837, COSV61005237; called by muse, mutect2, varscan2
- ATP6V1B1 | c.941G>A p.R314H | Missense Mutation (SNP) | VAF 153/667 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs782110679, COSV99314328; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GAPDH | c.394G>A p.V132I | Missense Mutation (SNP) | VAF 117/525 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.018); catalogued as rs745721511; called by muse, varscan2
- GYS2 | c.64G>T p.E22* | Nonsense Mutation (SNP) | VAF 313/1516 reads (21%) | catalogued as COSV53926029, COSV53926445; called by muse, mutect2, varscan2
- KLB | c.926G>A p.R309Q | Missense Mutation (SNP) | VAF 157/608 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.162); catalogued as rs772821024, COSV57305193; called by muse, mutect2, varscan2
- LRRC8C | c.709C>A p.Q237K | Missense Mutation (SNP) | VAF 254/780 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64995294; called by muse, mutect2, varscan2
- MUC17 | c.2242C>A p.P748T | Missense Mutation (SNP) | VAF 127/606 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.063); catalogued as COSV60285121, COSV60304184; called by muse, mutect2, varscan2
- NBPF9 | c.2617C>T p.P873S | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.57); catalogued as rs587721841; called by muse, mutect2, varscan2
- NLRP14 | c.2462+2dup p.X821_splice | Splice Site (INS) | VAF 98/682 reads (14%) | catalogued as rs1565023422; called by mutect2, varscan2
- SLC49A3 | c.566G>A p.G189D | Missense Mutation (SNP) | VAF 115/437 reads (26%) | SIFT tolerated (0.5); PolyPhen benign (0.105); catalogued as rs749785151; called by muse, mutect2, varscan2
- STAB1 | c.5785G>A p.V1929I | Missense Mutation (SNP) | VAF 131/404 reads (32%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs373901466; called by muse, mutect2, varscan2
- STIL | c.476G>A p.S159N | Missense Mutation (SNP) | VAF 225/788 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as rs1479547174; called by muse, mutect2, varscan2
- TLE4 | c.101G>A p.R34Q | Missense Mutation (SNP) | VAF 229/840 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV54632064; called by muse, mutect2, varscan2
- TNK2 | c.1495G>A p.V499M | Missense Mutation (SNP) | VAF 148/498 reads (30%) | SIFT tolerated (0.43); PolyPhen benign (0.028); catalogued as rs770236030; called by muse, varscan2
- ZFPM2 | c.3124G>A p.V1042I | Missense Mutation (SNP) | VAF 548/2796 reads (20%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.017); catalogued as rs545237723; called by muse, mutect2, varscan2
- CYP26C1 | c.861+2T>G p.X287_splice | Splice Site (SNP) | VAF 33/398 reads (8%) | called by muse, mutect2
- EFCAB8 | c.2999C>A p.A1000D | Missense Mutation (SNP) | VAF 108/787 reads (14%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.802); called by muse, mutect2, varscan2
- GBP2 | c.1169del p.R390Qfs*27 | Frame Shift Del (DEL) | VAF 152/508 reads (30%) | called by mutect2, varscan2
- JSRP1 | c.880G>A p.D294N | Missense Mutation (SNP) | VAF 43/126 reads (34%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- LGI2 | c.1602G>C p.K534N | Missense Mutation (SNP) | VAF 211/702 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- NPAT | c.658A>T p.T220S | Missense Mutation (SNP) | VAF 144/1010 reads (14%) | SIFT tolerated (0.53); PolyPhen benign (0); called by mutect2, varscan2
- NPAT | c.652_656del p.K218Yfs*28 | Frame Shift Del (DEL) | VAF 136/996 reads (14%) | called by mutect2, varscan2
- SNAI2 | c.514G>T p.G172C | Missense Mutation (SNP) | VAF 946/2440 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TOP2A | c.1060del p.H354Ifs*3 | Frame Shift Del (DEL) | VAF 116/435 reads (27%) | called by mutect2, varscan2
- ARID3A | c.552C>A p.R184= | Silent (SNP) | VAF 92/333 reads (28%) | called by muse, mutect2, varscan2
- CILP | c.402C>T p.T134= | Silent (SNP) | VAF 162/351 reads (46%) | catalogued as rs762196265; called by muse, mutect2, varscan2
- FAT4 | c.828C>T p.D276= | Silent (SNP) | VAF 152/476 reads (32%) | catalogued as COSV101271941; called by muse, mutect2, varscan2
- IGFLR1 | c.129G>A p.L43= | Silent (SNP) | VAF 132/480 reads (28%) | catalogued as rs1431957461; called by muse, mutect2, varscan2
- KSR2 | c.690C>T p.D230= | Silent (SNP) | VAF 70/281 reads (25%) | catalogued as rs1389531650; called by muse, mutect2, varscan2
- LRFN2 | c.864G>A p.P288= | Silent (SNP) | VAF 94/246 reads (38%) | catalogued as rs762359520, COSV100599532; called by muse, mutect2, varscan2
- MS4A14 | c.1890A>G p.Q630= | Silent (SNP) | VAF 260/1085 reads (24%) | called by muse, mutect2, varscan2
- OR2M4 | c.39C>T p.I13= | Silent (SNP) | VAF 167/600 reads (28%) | catalogued as rs1384491211, COSV60709414; called by muse, mutect2, varscan2
- SLCO1B1 | c.657T>A p.G219= | Silent (SNP) | VAF 44/1518 reads (3%) | called by muse, mutect2
- TOP2A | c.1059A>T p.A353= | Silent (SNP) | VAF 119/438 reads (27%) | called by mutect2, varscan2
- ARHGEF40 | c.3+467C>G | Intron (SNP) | VAF 81/298 reads (27%) | called by muse, mutect2, varscan2
- PDE4B | c.281+74283G>A | Intron (SNP) | VAF 30/980 reads (3%) | called by muse, mutect2
- TESPA1 | c.-42G>A | 5'UTR (SNP) | VAF 98/356 reads (28%) | catalogued as rs994114493; called by muse, mutect2, varscan2
